Somatic mutation profile of tumor specimen TARGET-20-PASYJI-09A (aliquot TARGET-20-PASYJI-09A-03D) from TARGET case TARGET-20-PASYJI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,545 days).
Specimen TARGET-20-PASYJI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e57ff7c9-e45c-4820-92da-742176e2dee3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASYJI-14A (Bone Marrow Normal), aliquot TARGET-20-PASYJI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/852c8344-f309-4c44-b9ae-16e568f38f0a

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: In Frame Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 26/284 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- KIT | c.1246_1255delinsTTAT p.T417_D419delinsY | In Frame Del (DEL) | VAF 74/240 reads (31%) | called by pindel, varscan2*
